Somatic mutation profile of tumor specimen 0DV5SC from CCDI case PBCKSA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,193 days).
Specimen 0DV5SC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7060f5bb-7594-4023-b8e8-59f41ef2006d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV5RO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb19bded-9b64-49b2-b135-d932a3e3c339

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 2, Frame Shift Ins 1, Silent 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT3 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 198/485 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397514606, COSV55605820, COSV55624598; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 243/562 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 276/658 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60785906, COSV60794673; called by muse, mutect2, varscan2
- ADA | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 447/1111 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs79249850; called by muse, mutect2, varscan2
- BCAM | c.1595G>A p.R532H | Missense Mutation (SNP) | VAF 277/676 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140735488, CM087623; called by muse, mutect2, varscan2
- DDX3X | c.661G>C p.A221P (on ENST00000399959; = p.A222P on NM_001356.5) | Missense Mutation (SNP) | VAF 186/207 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV104433640, COSV67863216; called by muse, mutect2, varscan2
- EGFR | c.1244C>G p.T415R | Missense Mutation (SNP) | VAF 413/942 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.469); catalogued as COSV51796395; called by muse, mutect2, varscan2
- NTHL1 | c.719del p.T240Sfs*10 (on ENST00000219066; = p.T232Sfs*10 on NM_002528.7 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/214 reads (34%) | catalogued as COSV54593981; called by mutect2, varscan2
- TRIO | c.6725C>T p.T2242M | Missense Mutation (SNP) | VAF 288/676 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs55916212, COSV59989891; called by muse, mutect2, varscan2
- ZMYM3 | c.3820C>T p.R1274W | Missense Mutation (SNP) | VAF 145/166 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs759700551, COSV100078478; called by muse, mutect2, varscan2
- ANKRD18A | c.1036A>C p.N346H | Missense Mutation (SNP) | VAF 99/802 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- GPC4 | c.1293-2A>G p.X431_splice | Splice Site (SNP) | VAF 191/200 reads (96%) | called by muse, mutect2, varscan2
- PARP14 | c.4406A>C p.E1469A | Missense Mutation (SNP) | VAF 26/798 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- RPL5 | c.491_492dup p.G165Rfs*48 | Frame Shift Ins (INS) | VAF 158/393 reads (40%) | called by mutect2, varscan2
- WDR4 | c.1111T>C p.Y371H | Missense Mutation (SNP) | VAF 294/710 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- WDR87 | c.4891G>C p.A1631P | Missense Mutation (SNP) | VAF 236/539 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KLHL23 | c.681C>T p.N227= | Silent (SNP) | VAF 32/812 reads (4%) | called by muse, mutect2
- LRRC7 | c.1421-34A>T | Intron (SNP) | VAF 18/222 reads (8%) | catalogued as rs1415560984; called by mutect2, varscan2
- TRPA1 | c.1195-74T>A | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, varscan2
